Somatic mutation profile of tumor specimen 0E0CT8 from CCDI case PBCVEK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E0CT8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13f264eb-a42a-4796-aeed-3c804b316632.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E0CV5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3013e91-5063-47bd-a7b3-2626f4640d9f

The open-access MAF lists 15 somatic variants for this specimen: 14 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 11, Nonsense Mutation 2, Silent 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APPBP2 | c.1639C>T p.R547* | Nonsense Mutation (SNP) | VAF 18/488 reads (4%) | catalogued as COSV50029227; called by muse, mutect2
- CLDN16 | c.418G>C p.V140L | Missense Mutation (SNP) | VAF 76/205 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.083); catalogued as rs1376923358; called by muse, mutect2, varscan2
- CLEC14A | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.051); catalogued as COSV60561956; called by muse, mutect2, varscan2
- COPA | c.3533G>A p.R1178H | Missense Mutation (SNP) | VAF 126/318 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs373521245; called by muse, mutect2, varscan2
- NCR1 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 52/353 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs746281091; called by muse, mutect2, varscan2
- NDNF | c.189-1G>T p.X63_splice | Splice Site (SNP) | VAF 29/342 reads (8%) | catalogued as COSV65634118; called by muse, mutect2
- THRA | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 57/573 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs770564120, COSV52841894; called by muse, mutect2
- UROS | c.10C>A p.L4I | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.916); catalogued as CM920704, COSV64223332; called by muse, mutect2, varscan2
- ARHGAP44 | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 186/232 reads (80%) | called by muse, mutect2, varscan2
- GOLGA6L2 | c.74C>A p.A25D | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- IL12B | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 168/442 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- OPRD1 | c.1105G>A p.G369S | Missense Mutation (SNP) | VAF 101/251 reads (40%) | SIFT tolerated (0.82); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RASEF | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RFX3 | c.1595C>T p.A532V | Missense Mutation (SNP) | VAF 130/331 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- ZNF644 | c.1833A>G p.S611= | Silent (SNP) | VAF 240/519 reads (46%) | called by muse, mutect2, varscan2
